Somatic mutation profile of tumor specimen TARGET-20-PARCCH-03A (aliquot TARGET-20-PARCCH-03A-02D) from TARGET case TARGET-20-PARCCH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.9 years (339 days).
Specimen TARGET-20-PARCCH-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2649be4-2391-436b-aa9a-6e896aeb54e6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCCH-14A (Bone Marrow Normal), aliquot TARGET-20-PARCCH-14A-03D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9427e50f-69ce-4300-a8b2-0c057a5ea9a0

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372460800; called by muse, mutect2, varscan2
